Somatic mutation profile of tumor specimen MP2PRT-PARCIY-TBP1-A (aliquot MP2PRT-PARCIY-TBP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PARCIY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,254 days).
Specimen MP2PRT-PARCIY-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6253c69d-31dc-4cbe-a79a-14f5e0556323.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARCIY-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARCIY-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ac5accf-2b76-4a3d-9315-9941b1d873f3

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 44/273 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 42/340 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BSN | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 20/500 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs895145949; called by muse, mutect2
- CAND2 | c.2713G>T p.E905* (on ENST00000456430 / NM_001162499.2; = p.E812* on NM_012298.3) | Nonsense Mutation (SNP) | VAF 166/576 reads (29%) | catalogued as COSV55988490; called by muse, mutect2, varscan2
- FAT2 | c.9489C>A p.D3163E | Missense Mutation (SNP) | VAF 62/598 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs754876966, COSV99941214; called by muse, mutect2, varscan2
- NELL2 | c.1616A>T p.N539I | Missense Mutation (SNP) | VAF 15/405 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- PCDH11X | c.1396T>A p.F466I | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IGF1 | c.108G>A p.A36= | Silent (SNP) | VAF 65/576 reads (11%) | catalogued as rs371125874; called by muse, mutect2, varscan2
- TKTL2 | c.1482C>A p.G494= | Silent (SNP) | VAF 18/491 reads (4%) | called by muse, mutect2
